Somatic mutation profile of tumor specimen TCGA-AB-2818-03B (aliquot TCGA-AB-2818-03B-01W-0728-08) from TCGA case TCGA-AB-2818, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.2 years (22,707 days).
Specimen TCGA-AB-2818-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8694a83-a89d-4928-965a-9eca86cfd83e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2818-11B (Solid Tissue Normal), aliquot TCGA-AB-2818-11B-01W-0728-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c8d4e33-b40a-4e63-ad0a-8e30a0fa0d71

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2503G>T p.D835Y | Missense Mutation (SNP) | VAF 30/81 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913488, COSV54042116, COSV54042636, COSV54045151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNMT3A | c.2409G>C p.R803S | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as COSV53077191; called by muse, mutect2, varscan2
- KLHL12 | c.1273A>C p.S425R | Missense Mutation (SNP) | VAF 109/228 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV66128062; called by muse, mutect2, varscan2
- LRRK1 | c.1375G>C p.E459Q | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.51); catalogued as rs1346889073, COSV99442273; called by muse, mutect2, varscan2
- TRPM8 | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs754089486, COSV61224149; called by muse, mutect2, varscan2
- LRRK1 | c.1374A>C p.S458= | Silent (SNP) | VAF 61/150 reads (41%) | catalogued as COSV99442270; called by muse, mutect2, varscan2
